Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LE, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LE-01A (Primary Tumor).

ICD-O-3

Carcinoma, adrenal cortical
8370/3

Site Adrenal Gland cortex
C740

gws 2/6/13

Procedure: L adrenalectomy and regional LN

Gross description: 17 x 15 x 15cm, 820g

Diagnosis: adrenocortical carcinoma, LN negative for tumor

Reference Pathology:

Diagnosis: adrenocortical carcinoma, KI67 2%

Weiss score: 5

Hough score: 2.6

Van Slooten score: 19.7

Source: NCI Genomic Data Commons file d40990ba-be3d-4231-a0a3-ce97609c6a9f (TCGA-OR-A5LE.5F38424F-73C9-41F5-B183-6A812A65593A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).